Somatic mutation profile of tumor specimen 0DWYWM from CCDI case PBCPSX, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Ependymoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 4.5 years (1,642 days).
Specimen 0DWYWM: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 96c4f40f-4d04-42a8-a806-f18b003d029e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DWYUV (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/adc53569-9ebb-458e-95da-7ab7fb7428ca

The open-access MAF lists 7 somatic variants for this specimen: 3 protein-altering or splice-affecting, 2 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 2, 3'UTR 2, Missense Mutation 2, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PSMD13 | c.648+1G>C p.X216_splice | Splice Site (SNP) | VAF 43/372 reads (12%) | catalogued as rs112028665, COSV61501612; called by muse, mutect2, varscan2
- RUNDC1 | c.1810C>T p.R604C | Missense Mutation (SNP) | VAF 162/710 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs749602274, COSV64511705; called by muse, mutect2, varscan2
- WDR87 | c.8522T>C p.I2841T | Missense Mutation (SNP) | VAF 74/294 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- ATP8A1 | c.3075C>T p.Y1025= | Silent (SNP) | VAF 27/716 reads (4%) | called by muse, mutect2
- TRIO | c.7782C>T p.A2594= | Silent (SNP) | VAF 42/490 reads (9%) | catalogued as rs762432411, COSV59990213; called by muse, mutect2
- IRF8 | c.*8G>A | 3'UTR (SNP) | VAF 64/262 reads (24%) | catalogued as rs762649380, COSV51900571; called by muse, mutect2, varscan2
- TSEN34 | c.*32G>A | 3'UTR (SNP) | VAF 43/280 reads (15%) | catalogued as rs532938622; called by muse, mutect2, varscan2
